Somatic mutation profile of tumor specimen TCGA-ET-A2N1-01A (aliquot TCGA-ET-A2N1-01A-11D-A18F-08) from TCGA case TCGA-ET-A2N1, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 47.3 years (17,272 days).
Specimen TCGA-ET-A2N1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25e4882d-9429-43bd-857c-d0890e973858.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A2N1-10A (Blood Derived Normal), aliquot TCGA-ET-A2N1-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2707f068-69b6-4ab0-8852-6b11280077e8

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 4, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MRPS31 | c.607A>T p.N203Y | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1335537372, COSV60268635; called by muse, mutect2, varscan2
- RABEP2 | c.1117C>A p.L373M | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.549); catalogued as COSV62870776; called by muse, mutect2, varscan2
- SLCO6A1 | c.1835G>A p.R612H | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.061); catalogued as rs764746269, COSV65814129; called by muse, mutect2, varscan2
- YEATS4 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56089679; called by muse, mutect2
- CORO7 | c.1764T>G p.T588= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV52033465; called by muse, mutect2, varscan2
- FAM83E | c.78A>G p.L26= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1407846500, COSV50032294; called by muse, mutect2, varscan2
- NGFR | c.483G>A p.V161= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV50803988; called by muse, mutect2, varscan2
- NPAP1 | c.2262G>A p.R754= | Silent (SNP) | VAF 10/221 reads (5%) | catalogued as COSV61510612; called by muse, mutect2
